Somatic mutation profile of tumor specimen ALCH-B0E2-TTP1-A (aliquot ALCH-B0E2-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0E2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.0 years (28,136 days).
Specimen ALCH-B0E2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b80bd80-11f5-4465-8a56-259697907332.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0E2-NB1-A (Blood Derived Normal), aliquot ALCH-B0E2-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd87eb81-ee60-4d7b-8f91-b3e921262108

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Intron 4, Nonsense Mutation 2, Splice Region 2, 3'UTR 2, 3'Flank 1, RNA 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.3998C>A p.T1333K | Missense Mutation (SNP) | VAF 30/1005 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV71433241; called by muse, mutect2
- MYT1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 15/508 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1045771733; called by muse, mutect2
- TRAPPC8 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99350509; called by muse, mutect2
- UBE2I | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV57646720; called by muse, mutect2
- WT1 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV60084364, COSV60086195; called by muse, mutect2
- ADGRL3 | c.3222T>A p.Y1074* (on ENST00000506720 / NM_001322402.2; = p.Y1006* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- BTBD11 | c.992A>T p.N331I | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- CAMK4 | c.303T>A p.I101= | Splice Region (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
- CAMKV | c.1394C>A p.A465D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- CAPN6 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2
- DNAH5 | c.10324C>T p.Q3442* | Nonsense Mutation (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- DNAH9 | c.6630G>T p.M2210I | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2
- ERICH3 | c.3661G>T p.A1221S | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FLG | c.10921G>T p.G3641C | Missense Mutation (SNP) | VAF 52/1190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHG1 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGLV2-33 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.175); called by muse, mutect2
- KYNU | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 23/755 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MUC16 | c.17353A>T p.R5785W | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.336); called by muse, mutect2
- OR11A1 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- OR14J1 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- PSG4 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 31/745 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.145); called by muse, mutect2
- SEMA7A | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SH3KBP1 | c.1956G>A p.Q652= | Splice Region (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- STON1-GTF2A1L | c.3018G>T p.R1006S | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2
- ZNF229 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP25 | c.1485T>A p.S495= (on ENST00000409202 / NM_001007231.3; = p.S487= on NM_014882.3) | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- MYBPC1 | c.336G>A p.L112= (on ENST00000550270 / NM_206820.2; = p.L137= on NM_002465.4) | Silent (SNP) | VAF 17/495 reads (3%) | called by muse, mutect2
- OR2G6 | c.459C>T p.L153= | Silent (SNP) | VAF 20/356 reads (6%) | catalogued as COSV58575237; called by muse, mutect2
- OR2M2 | c.171C>A p.T57= | Silent (SNP) | VAF 27/335 reads (8%) | catalogued as rs1558246264, COSV62898141; called by muse, mutect2
- AC107023.1 | chr12:40444412 T>C | 5'Flank (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- ADAMTS6 | c.1370+2786G>T | Intron (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- ARHGEF6 | c.-11C>A | 5'UTR (SNP) | VAF 14/242 reads (6%) | catalogued as COSV99166320; called by muse, mutect2
- CD33 | c.924+23A>G | Intron (SNP) | VAF 12/333 reads (4%) | called by muse, mutect2
- DCHS2 | n.1178T>C | RNA (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- MMAB | c.*2430C>G | 3'UTR (SNP) | VAF 19/644 reads (3%) | called by muse, mutect2
- MMP26 | c.-145+93109G>T | Intron (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- MYPN | c.*559G>C | 3'UTR (SNP) | VAF 21/684 reads (3%) | catalogued as rs1252520939; called by muse, mutect2
- SYT14 | chr1:210163790 A>T | 3'Flank (SNP) | VAF 15/392 reads (4%) | called by muse, mutect2
- WDR62 | c.1233+144G>C | Intron (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
